Somatic mutation profile of tumor specimen 0DTYB8 from CCDI case PBCKDS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.7 years (2,821 days).
Specimen 0DTYB8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8f2b6a1-fbec-4da2-81f9-d0ce0642ae3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTYAW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f21e9422-6bd0-4e3f-8b58-51cc00bca294

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KL | c.2922T>G p.S974R | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.142); catalogued as COSV66308205; called by muse, mutect2
- MMP27 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 170/384 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1330299959, COSV52780539, COSV52782302; called by muse, mutect2, varscan2
- NALCN | c.2204G>A p.R735Q | Missense Mutation (SNP) | VAF 181/459 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs145128255; called by muse, mutect2, varscan2
- TRMT13 | c.1391A>G p.N464S | Missense Mutation (SNP) | VAF 15/438 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1444259616; called by muse, mutect2
- KRT16 | c.1229T>C p.L410P | Missense Mutation (SNP) | VAF 17/457 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSPG4 | c.5820C>T p.S1940= | Silent (SNP) | VAF 74/249 reads (30%) | catalogued as rs757170407, COSV100413905; called by muse, mutect2, varscan2
- DOCK10 | c.3597C>A p.A1199= | Silent (SNP) | VAF 123/289 reads (43%) | called by muse, mutect2, varscan2
- ZNF775 | c.1539G>A p.Q513= | Silent (SNP) | VAF 104/282 reads (37%) | catalogued as rs776204916; called by muse, mutect2, varscan2
- CRLF2 | c.*56A>T | 3'UTR (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
